Somatic mutation profile of tumor specimen C3N-01997-02 (aliquot CPT0138900010) from CPTAC case C3N-01997, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.4 years (23,169 days).
Specimen C3N-01997-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd04abb3-f59e-4b1b-a5a5-de5747fa6d12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01997-71 (Blood Derived Normal), aliquot CPT0138920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dbc3256-8c6b-4ae5-89d4-5b4d37f4f998

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ADGRB2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57079678; called by muse, mutect2, varscan2
- CEP19 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356324447; called by muse, mutect2
- FGF10 | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1453394033, COSV99240857; called by muse, mutect2
- LPCAT2 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 12/137 reads (9%) | catalogued as rs1360979777; called by muse, mutect2
- MORC2 | c.698C>T p.T233M (on ENST00000397641 / NM_001303256.3; = p.T171M on NM_014941.3) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.894); catalogued as rs924468105; called by muse, mutect2
- PPP1R3A | c.3069A>C p.E1023D | Missense Mutation (SNP) | VAF 16/443 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.318); catalogued as COSV52893421; called by muse, mutect2
- PRSS16 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756472444; called by muse, mutect2
- TTN | c.66634G>A p.D22212N (on ENST00000591111; = p.D14788N on NM_003319.4) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs1387991752; called by muse, mutect2, varscan2
- ZNF813 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs764637390, COSV67175591; called by muse, mutect2
- CCNK | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.5); called by muse, mutect2
- ERCC3 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- KCNN2 | c.1171G>T p.A391S (on ENST00000264773; = p.A603S on NM_021614.4) | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- KIF26B | c.5581C>T p.H1861Y | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- LRP12 | c.1654T>A p.L552M | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MLNR | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- PDE11A | c.2033C>G p.A678G | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); called by muse, mutect2
- SKIDA1 | c.1639A>G p.N547D | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- SS18 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- TBCB | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- ZBTB39 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.03); called by muse, mutect2
- ALPK3 | c.3867C>G p.S1289= | Silent (SNP) | VAF 34/274 reads (12%) | catalogued as rs188837127, COSV51936632; called by muse, mutect2, varscan2
- GRM1 | c.2346C>T p.N782= | Silent (SNP) | VAF 71/567 reads (13%) | catalogued as rs145874853; ClinVar: likely benign; called by muse, mutect2, varscan2
- INHBB | c.135C>A p.P45= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- KRT82 | c.990C>T p.R330= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs1291756887; called by muse, mutect2
- LRP4 | c.4974T>A p.A1658= | Silent (SNP) | VAF 48/536 reads (9%) | called by muse, mutect2
- MED13 | c.111C>G p.G37= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as rs746555652; called by muse, mutect2
- NOS3 | c.2076G>A p.E692= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as rs778063544; called by muse, mutect2
- RAD54B | c.675G>A p.R225= | Silent (SNP) | VAF 24/384 reads (6%) | called by muse, mutect2
- RP1 | c.5679C>A p.G1893= | Silent (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- TRIM47 | c.498C>T p.R166= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1263791507; called by muse, mutect2
- ZNF521 | c.3111C>A p.I1037= | Silent (SNP) | VAF 69/279 reads (25%) | catalogued as COSV100833290; called by muse, mutect2, varscan2
